Somatic mutation profile of cancer-model specimen HCM-STAN-1109-D13-85B (3D Organoid, passage 8; aliquot HCM-STAN-1109-D13-85B-01D-A937-36), derived from the primary tumor of HCMI case HCM-STAN-1109-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage 0.
Specimen HCM-STAN-1109-D13-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a8e504c-fafe-4bad-a370-5df773e3fa61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-1109-D13-11A (Solid Tissue Normal), aliquot HCM-STAN-1109-D13-11A-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67625366-dad9-4eed-abc8-7764075c83d0

The open-access MAF lists 91 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 18, Frame Shift Del 3, 5'Flank 3, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 146/153 reads (95%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AGL | c.2690C>G p.S897C | Missense Mutation (SNP) | VAF 124/244 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1166549253; called by muse, mutect2, varscan2
- AKAP6 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 244/524 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1248907673; called by muse, mutect2
- BMPR1A | c.1394C>G p.P465R | Missense Mutation (SNP) | VAF 168/173 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408953; called by muse, mutect2, varscan2
- CDH9 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 160/332 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564401936, COSV50282071, COSV50318030; called by muse, mutect2, varscan2
- COLEC11 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 257/614 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs769978108, COSV52592400; called by muse, varscan2
- DDX21 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 137/300 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100826509; called by muse, mutect2, varscan2
- DNAH5 | c.9688G>T p.E3230* | Nonsense Mutation (SNP) | VAF 144/336 reads (43%) | catalogued as COSV54203076; called by muse, mutect2, varscan2
- DNAJB2 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60676064; called by muse, mutect2
- FBLN5 | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV50905230, COSV50907908; called by muse, mutect2, varscan2
- FBRSL1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 296/672 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs371082354; called by muse, mutect2, varscan2
- GRXCR1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 179/376 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV67671586; called by muse, mutect2, varscan2
- HBG2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 121/331 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100400738; called by muse, mutect2, varscan2
- HOXD1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 244/517 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV100514192; called by muse, varscan2
- ITIH2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as rs267602582, COSV64432176; called by muse, mutect2, varscan2
- LRRC49 | c.1063_1065del p.R355del | In Frame Del (DEL) | VAF 149/325 reads (46%) | catalogued as rs1275377468; called by mutect2, varscan2
- MAGEB6 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 248/336 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as rs774043480; called by muse, mutect2, varscan2
- MUC16 | c.40471C>T p.R13491W | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs541610415, COSV66689793, COSV66695495; called by muse, varscan2
- NAV3 | c.4492C>T p.R1498C | Missense Mutation (SNP) | VAF 195/375 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770042276; called by muse, mutect2, varscan2
- NPAS4 | c.381C>A p.D127E | Missense Mutation (SNP) | VAF 183/366 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60651182; called by mutect2, varscan2
- NRXN1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 280/556 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs1166363453, COSV68014859; called by muse, mutect2, varscan2
- OR5D18 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 231/484 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs761012413; called by muse, mutect2, varscan2
- PCDHA6 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 362/773 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs536607224, COSV65343503; called by muse, varscan2
- PCDHGA4 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 303/614 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as rs747114366, COSV53901792; called by muse, mutect2, varscan2
- PMS2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs200726484, COSV99764327; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN10A | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 206/419 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1161786818; called by muse, mutect2, varscan2
- SFTPA2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 104/195 reads (53%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.026); catalogued as rs762122845; called by muse, mutect2, varscan2
- SLC17A7 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 202/372 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1360805794; called by muse, mutect2, varscan2
- TGM6 | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 177/339 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV104390283, COSV99171707; called by muse, mutect2, varscan2
- THSD7B | c.1655G>T p.C552F | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777290058; called by muse, mutect2, varscan2
- TPTE | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 185/532 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759630343; called by muse, mutect2, varscan2
- TTN | c.2735G>A p.R912H (on ENST00000591111; = p.R866H on NM_003319.4) | Missense Mutation (SNP) | VAF 182/379 reads (48%) | PolyPhen benign (0.003); catalogued as rs766770644; called by muse, mutect2, varscan2
- ZNF214 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs772167149; called by muse, varscan2
- ZNF273 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV60400845; called by muse, mutect2, varscan2
- ZNF646 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 340/632 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763822772; called by muse, mutect2, varscan2
- AKNA | c.2495A>G p.E832G | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- APLNR | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 280/560 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ARHGAP20 | c.1085T>A p.L362H | Missense Mutation (SNP) | VAF 201/401 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GALT6 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 272/598 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.148); called by muse, varscan2
- BMPR1A | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 150/152 reads (99%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C2orf16 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CACNA1I | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 303/624 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EBF1 | c.536A>G p.D179G | Missense Mutation (SNP) | VAF 151/371 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELF1 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAT3 | c.6296C>A p.P2099H | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW2 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 187/353 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FTMT | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 189/399 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- GNAQ | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 164/350 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.063); called by muse, varscan2
- IFITM5 | c.314T>G p.V105G | Missense Mutation (SNP) | VAF 247/507 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KIAA0232 | c.1579A>G p.M527V | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAPTM4A | c.437_462del p.D146Gfs*22 | Frame Shift Del (DEL) | VAF 76/268 reads (28%) | called by mutect2, varscan2
- LILRB1 | c.1449del p.T484Pfs*29 (on ENST00000427581; = p.T447Pfs*16 on NM_006669.6) | Frame Shift Del (DEL) | VAF 285/581 reads (49%) | called by mutect2, varscan2
- NDST3 | c.1602T>G p.F534L | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- PALM2AKAP2 | c.2204del p.E735Gfs*2 (on ENST00000259318 / NM_001136562.3; = p.E966Gfs*2 on NM_007203.5) | Frame Shift Del (DEL) | VAF 204/438 reads (47%) | called by mutect2, varscan2
- PCDH17 | c.803C>G p.T268S | Missense Mutation (SNP) | VAF 202/451 reads (45%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PKP4 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 197/381 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POTEI | c.2294T>A p.L765Q | Missense Mutation (SNP) | VAF 171/485 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEPTIN8 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 248/487 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC12A4 | c.1547G>T p.C516F | Missense Mutation (SNP) | VAF 18/576 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2
- SMARCA4 | c.3046_3063del p.V1016_G1021del | In Frame Del (DEL) | VAF 108/362 reads (30%) | called by mutect2, varscan2
- STAB2 | c.3980G>T p.C1327F | Missense Mutation (SNP) | VAF 20/401 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TAAR2 | c.1033T>A p.C345S (on ENST00000367931 / NM_001033080.1; = p.C300S on NM_014626.3) | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TLN2 | c.3689T>A p.L1230Q | Missense Mutation (SNP) | VAF 149/329 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- TMPRSS11F | c.994T>C p.F332L | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRAF2 | c.337A>C p.T113P | Missense Mutation (SNP) | VAF 178/365 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPM4 | c.2681T>C p.V894A | Missense Mutation (SNP) | VAF 249/456 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TSPAN19 | c.564T>A p.C188* | Nonsense Mutation (SNP) | VAF 161/341 reads (47%) | called by muse, mutect2, varscan2
- ULBP2 | c.653G>C p.G218A | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZNF16 | c.1658C>A p.T553N | Missense Mutation (SNP) | VAF 188/526 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AC113554.1 | c.2205A>G p.P735= | Silent (SNP) | VAF 171/357 reads (48%) | called by muse, mutect2, varscan2
- B4GALT7 | c.847A>C p.R283= | Silent (SNP) | VAF 169/359 reads (47%) | catalogued as rs777167322; called by muse, mutect2, varscan2
- CAPRIN1 | c.1587T>G p.V529= | Silent (SNP) | VAF 177/326 reads (54%) | called by muse, mutect2, varscan2
- CERS6 | c.303C>G p.G101= | Silent (SNP) | VAF 123/302 reads (41%) | called by muse, mutect2, varscan2
- DDHD1 | c.618A>T p.S206= (on ENST00000323669; = p.S403= on NM_030637.3) | Silent (SNP) | VAF 219/491 reads (45%) | called by muse, mutect2, varscan2
- DSCAML1 | c.2913C>T p.F971= (on ENST00000321322; = p.F911= on NM_020693.4) | Silent (SNP) | VAF 161/424 reads (38%) | catalogued as rs149232264; called by muse, varscan2
- FAM111B | c.822A>G p.L274= | Silent (SNP) | VAF 154/297 reads (52%) | catalogued as rs756262360; called by muse, mutect2, varscan2
- GPN2 | c.39G>A p.A13= | Silent (SNP) | VAF 236/463 reads (51%) | catalogued as rs1339271465; called by muse, mutect2, varscan2
- IGKV6D-21 | c.63T>C p.I21= | Silent (SNP) | VAF 58/169 reads (34%) | called by muse, mutect2, varscan2
- INO80D | c.243A>T p.V81= | Silent (SNP) | VAF 149/322 reads (46%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.3708G>A p.S1236= | Silent (SNP) | VAF 259/622 reads (42%) | catalogued as rs527556036; called by muse, mutect2, varscan2
- MUC16 | c.27804A>C p.S9268= | Silent (SNP) | VAF 229/498 reads (46%) | called by muse, mutect2, varscan2
- OR4B1 | c.849C>A p.I283= | Silent (SNP) | VAF 250/541 reads (46%) | called by muse, mutect2, varscan2
- PKHD1 | c.7041C>G p.L2347= | Silent (SNP) | VAF 168/356 reads (47%) | catalogued as COSV61885017; called by muse, varscan2
- PSTPIP1 | c.375G>T p.R125= | Silent (SNP) | VAF 173/347 reads (50%) | called by muse, mutect2, varscan2
- SIM2 | c.1824G>C p.R608= | Silent (SNP) | VAF 138/293 reads (47%) | catalogued as rs1478136233; called by muse, mutect2, varscan2
- STOX2 | c.2340C>T p.D780= | Silent (SNP) | VAF 199/425 reads (47%) | catalogued as rs369886997, COSV57857904; called by muse, mutect2, varscan2
- TENM3 | c.4308A>T p.G1436= | Silent (SNP) | VAF 241/509 reads (47%) | called by muse, mutect2, varscan2
- C4orf50 | chr4:5990123 G>T | 5'Flank (SNP) | VAF 163/339 reads (48%) | catalogued as rs1446072577; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+26636G>C | Intron (SNP) | VAF 127/304 reads (42%) | called by muse, mutect2, varscan2
- MIR4458 | chr5:8460002 A>T | 5'Flank (SNP) | VAF 167/316 reads (53%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611781 T>A | 5'Flank (SNP) | VAF 52/281 reads (19%) | called by muse, mutect2, varscan2
